Somatic mutation profile of tumor specimen TCGA-XE-A8H5-01A (aliquot TCGA-XE-A8H5-01A-11D-A435-10) from TCGA case TCGA-XE-A8H5, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 30.0 years (10,942 days).
Specimen TCGA-XE-A8H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09b8b390-4ba5-4b44-8787-2b484de01a0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-A8H5-10A (Blood Derived Normal), aliquot TCGA-XE-A8H5-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6a76381-d673-4972-826c-d645e4ccd6a7

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Nonsense Mutation 4, Intron 2, In Frame Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 34/656 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 75/293 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARMH3 | c.991A>G p.S331G | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1361150869; called by muse, mutect2, varscan2
- C2CD2L | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355191415; called by muse, mutect2
- DND1 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56908117; called by muse, mutect2, varscan2
- GATAD2A | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs765936748; called by muse, mutect2
- KCNK9 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100271438; called by muse, mutect2, varscan2
- MUC19 | c.436T>C p.S146P | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); catalogued as rs1179356202; called by muse, mutect2, varscan2
- PTBP1 | c.1000G>A p.A334T (on ENST00000349038 / NM_031991.4; = p.A360T on NM_002819.5) | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1225313667; called by muse, mutect2, varscan2
- RTL6 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as rs1569000169; called by muse, mutect2, varscan2
- ZNF432 | c.15G>A p.Q5= | Splice Region (SNP) | VAF 27/142 reads (19%) | catalogued as rs1342276985; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2524A>T p.R842W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- COL12A1 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CPED1 | c.1984_2010del p.L662_P670del | In Frame Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, pindel
- CPT1A | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); called by muse, mutect2
- FRY | c.1220T>G p.L407R | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPR1 | c.5921A>G p.Q1974R (on ENST00000354582; = p.Q1919R on NM_002222.7) | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRP1B | c.6311C>T p.A2104V | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- MTIF3 | c.385C>A p.Q129K | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- MUC5B | c.13174C>T p.L4392F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NEUROG3 | c.29C>G p.T10S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOTCH1 | c.5386C>A p.P1796T | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PPP1R17 | c.181A>T p.K61* | Nonsense Mutation (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- RCN1 | c.476C>A p.S159* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- SNTG1 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 121/793 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TATDN1 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 45/246 reads (18%) | called by muse, mutect2, varscan2
- TCOF1 | c.4216G>T p.G1406W (on ENST00000377797 / NM_001135243.1; = p.G1329W on NM_000356.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- WNK1 | c.1417C>T p.L473F | Missense Mutation (SNP) | VAF 44/559 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF717 | c.2214A>C p.K738N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- H3C3 | c.196C>T p.L66= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs756032161; called by muse, mutect2, varscan2
- MAPT | c.825G>A p.G275= (on ENST00000262410 / NM_001377265.1; = p.G200= on NM_016835.4) | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs1400418963; called by muse, mutect2, varscan2
- MYOM3 | c.2505C>T p.G835= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- ROGDI | c.495C>T p.T165= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs963528275; called by muse, mutect2
- RORC | c.1338G>T p.L446= | Silent (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- ADGB | c.4818+5538C>G | Intron (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- PPY | c.*10C>A | 3'UTR (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- ZC2HC1A | c.93+12G>T | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
